Somatic mutation profile of tumor specimen TCGA-QR-A70E-01A (aliquot TCGA-QR-A70E-01A-11D-A35D-08) from TCGA case TCGA-QR-A70E, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 31.2 years (11,400 days).
Specimen TCGA-QR-A70E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f013cb4-75d7-4c80-8f30-13691401f6af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70E-10A (Blood Derived Normal), aliquot TCGA-QR-A70E-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84550746-0f05-41ae-874e-0f1a5740b4e4

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCAF1 | c.3468G>T p.W1156C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100244629; called by muse, mutect2
- LAMA3 | c.5414G>A p.C1805Y (on ENST00000313654 / NM_198129.4; = p.C196Y on NM_000227.6) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs868023831, COSV99334266; called by muse, mutect2
- ME3 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as COSV100660867, COSV62771883; called by muse, mutect2, varscan2
- HUWE1 | c.7406A>G p.E2469G | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KLRC2 | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RSRC2 | c.653_658del p.S218_R219del | In Frame Del (DEL) | VAF 6/75 reads (8%) | called by mutect2, pindel
- RXRB | c.1337T>C p.L446P | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX10 | c.326A>T p.D109V | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A12 | c.345G>A p.P115= | Silent (SNP) | VAF 26/29 reads (90%) | catalogued as rs776503281, COSV60572020; called by muse, mutect2, varscan2
